Somatic mutation profile of tumor specimen TCGA-GU-A42P-01A (aliquot TCGA-GU-A42P-01A-11D-A23U-08) from TCGA case TCGA-GU-A42P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 72.7 years (26,546 days).
Specimen TCGA-GU-A42P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bed0682f-87f3-4242-a49d-180b0b45fdac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GU-A42P-10A (Blood Derived Normal), aliquot TCGA-GU-A42P-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fab6e5ef-f79d-4ab4-a16a-e443513a5c75

The open-access MAF lists 299 somatic variants for this specimen: 196 protein-altering or splice-affecting, 98 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 98, Nonsense Mutation 19, Frame Shift Del 3, 3'Flank 2, Splice Site 2, Frame Shift Ins 2, Splice Region 2, Intron 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 46/49 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2032G>T p.E678* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100382509; called by muse, mutect2, varscan2
- ABCA9 | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100382510; called by muse, mutect2
- ACOX2 | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100250038, COSV57149969; called by muse, mutect2, varscan2
- ADAM8 | c.2456G>T p.G819V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV69865006; called by muse, mutect2, varscan2
- ADAMDEC1 | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as COSV56476442; called by muse, mutect2, varscan2
- ADAMTS12 | c.3842C>G p.S1281C | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV61260943, COSV61270346; called by muse, mutect2
- ADGRF1 | c.1811T>C p.L604P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51946651; called by muse, mutect2, varscan2
- ADGRL3 | c.3537C>G p.F1179L (on ENST00000506720 / NM_001322402.2; = p.F1111L on NM_015236.6) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.895); catalogued as COSV72230089, COSV72231288; called by muse, mutect2, varscan2
- ADRM1 | c.954G>C p.E318D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as COSV53365573; called by muse, mutect2, varscan2
- ALDH1L1 | c.1821G>C p.L607F | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56416670; called by muse, mutect2, varscan2
- ALYREF | c.374C>G p.S125* | Nonsense Mutation (SNP) | VAF 14/141 reads (10%) | catalogued as COSV100485740; called by muse, mutect2, varscan2
- ANKRD55 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61948671; called by muse, mutect2, varscan2
- ARID1A | c.2830C>T p.Q944* | Nonsense Mutation (SNP) | VAF 53/79 reads (67%) | catalogued as COSV61374989; called by muse, mutect2, varscan2
- ARMH4 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1255036553, COSV50768484; called by muse, mutect2, varscan2
- ASPSCR1 | c.1353G>A p.Q451= | Splice Region (SNP) | VAF 32/96 reads (33%) | catalogued as COSV60730012; called by muse, mutect2, varscan2
- ATG2B | c.3968A>G p.K1323R | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55891468; called by muse, mutect2, varscan2
- ATG9B | c.977C>G p.S326W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as COSV99871055; called by muse, mutect2, varscan2
- ATP5F1A | c.1658C>G p.A553G | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as COSV56361163; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372252307, COSV59478063; called by muse, mutect2, varscan2
- AUTS2 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as rs976081207, COSV100719314, COSV61418157; called by muse, mutect2, varscan2
- BACE2 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1377506643, COSV57737272; called by muse, mutect2, varscan2
- BNIP5 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs140376441; called by muse, mutect2, varscan2
- BTK | c.1347G>T p.M449I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100437236; called by muse, mutect2
- C12orf43 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- CAPN2 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs759517694, COSV54337783; called by muse, mutect2, varscan2
- CATSPER1 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV56412175; called by muse, mutect2, varscan2
- CCDC62 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as rs868358982, COSV99456513; called by muse, mutect2, varscan2
- CCDC88C | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV66239741; called by muse, mutect2, varscan2
- CCHCR1 | c.1850C>A p.S617* | Nonsense Mutation (SNP) | VAF 83/408 reads (20%) | catalogued as COSV99458505; called by muse, mutect2, varscan2
- CD300E | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as COSV60790899; called by muse, mutect2, varscan2
- CDH12 | c.356G>C p.R119T | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66425703, COSV66445567; called by muse, mutect2, varscan2
- CHD3 | c.3178G>A p.G1060R | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57872170, COSV57877830; called by muse, mutect2, varscan2
- CHL1 | c.739G>A p.E247K (on ENST00000397491 / NM_001253387.1; = p.E263K on NM_006614.4) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.031); catalogued as COSV56588523; called by muse, mutect2
- CHPF2 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs745887636, COSV50388903; called by muse, mutect2, varscan2
- CIT | c.1015C>G p.Q339E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV99948047; called by muse, mutect2
- CLEC3A | c.578G>A p.R193H (on ENST00000651443; = p.R184H on NM_005752.6) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs201495730, COSV55221440, COSV55224438; called by muse, mutect2, varscan2
- CNTNAP2 | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV62220792; called by muse, mutect2
- COG4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs387907202, CM110993, COSV60422122; called by muse, mutect2, varscan2
- CRB1 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 98/135 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV66331903; called by muse, mutect2, varscan2
- CRYBG2 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.311); catalogued as rs1557720250; called by muse, mutect2
- CSMD1 | c.2239G>T p.V747F (on ENST00000520002; = p.V746F on NM_033225.6) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV59351960; called by muse, mutect2, varscan2
- DBH | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV55042460; called by muse, mutect2, varscan2
- DCAF12L2 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63583212, COSV63584206; called by muse, mutect2, varscan2
- DNAJC13 | c.5691G>T p.M1897I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99606334; called by muse, mutect2, varscan2
- DUS1L | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1000903772; called by muse, mutect2
- E2F8 | c.1805G>C p.R602T | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV51464918; called by muse, mutect2, varscan2
- ECE1 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.351); catalogued as rs754109847, COSV51662852; called by muse, mutect2, varscan2
- ECM2 | c.1865C>G p.S622C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV60738942; called by muse, mutect2
- EMC3 | c.380G>A p.W127* | Nonsense Mutation (SNP) | VAF 7/79 reads (9%) | catalogued as COSV99793841; called by muse, mutect2
- EPHA10 | c.1856C>A p.T619K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV57625491; called by muse, mutect2, varscan2
- EPHA8 | c.228G>C p.M76I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV51278887; called by muse, mutect2, varscan2
- FAXDC2 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100394092; called by muse, mutect2, varscan2
- FBXO42 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as rs760530903, COSV65046371; called by muse, mutect2, varscan2
- FILIP1L | c.3007C>T p.Q1003* (on ENST00000354552 / NM_182909.3; = p.Q763* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as COSV100496080; called by muse, mutect2, varscan2
- FLAD1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 75/96 reads (78%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV52698392; called by muse, mutect2, varscan2
- FLRT2 | c.317A>G p.N106S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV58146377; called by muse, mutect2
- FXR1 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV59764578; called by muse, mutect2, varscan2
- FZD3 | c.978del p.A328Hfs*15 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as COSV53536768; called by pindel, varscan2
- GDAP1L1 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV61158120; called by muse, mutect2
- GGNBP2 | c.1818G>C p.Q606H | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated, low confidence (0.56); PolyPhen possibly damaging (0.466); catalogued as rs1567836718; called by muse, mutect2, varscan2
- GINS4 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); catalogued as COSV52531888, COSV99394703; called by muse, mutect2, varscan2
- GLI3 | c.4258G>A p.G1420S | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); catalogued as rs753656456, COSV67891718; called by muse, mutect2, varscan2
- GOLGA3 | c.1798C>G p.Q600E | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV52637593; called by muse, mutect2
- GPC5 | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs1164190037, COSV65599418; called by muse, mutect2, varscan2
- GPR37L1 | c.857G>A p.C286Y | Missense Mutation (SNP) | VAF 62/81 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66162606; called by muse, mutect2, varscan2
- GRIN2A | c.4126C>T p.R1376C | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs1426934537, COSV58023359, COSV58024387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2B | c.3559C>T p.H1187Y | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.013); catalogued as rs1310211364, COSV74206844; called by muse, mutect2, varscan2
- H4C12 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100694732, COSV100694790, COSV100694810; called by muse, mutect2, varscan2
- HCFC2 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57559267; called by muse, mutect2
- HIF3A | c.670G>A p.E224K (on ENST00000377670 / NM_152795.4; = p.E155K on NM_022462.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs771340596, COSV52201907; called by muse, mutect2, varscan2
- HNF1B | c.342C>T p.L114= | Splice Region (SNP) | VAF 16/156 reads (10%) | catalogued as CD063625; called by muse, mutect2
- HTR1D | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs776156764, COSV58448643; called by muse, mutect2, varscan2
- ICE1 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as rs1271908001, COSV56825670; called by muse, mutect2
- IFT172 | c.2929C>G p.Q977E | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs1430982419, COSV53136505; called by muse, mutect2, varscan2
- IKZF1 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV58783686, COSV58790701; called by muse, mutect2, varscan2
- IQCA1 | c.1667T>C p.L556S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1156388001, COSV54496390, COSV54507422; called by muse, mutect2, varscan2
- KBTBD7 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV65266875; called by muse, mutect2, varscan2
- KCNH6 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100121024, COSV59001390; called by muse, mutect2, varscan2
- KCNQ3 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867625794, COSV66476278; called by muse, mutect2, varscan2
- KIAA1109 | c.6440G>A p.W2147* | Nonsense Mutation (SNP) | VAF 60/91 reads (66%) | catalogued as COSV99145400; called by muse, mutect2, varscan2
- KLHL12 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV66126051; called by muse, mutect2
- KLRC3 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101122885; called by muse, mutect2
- KTI12 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); catalogued as COSV65405968; called by muse, mutect2, varscan2
- LMTK3 | c.3511G>C p.E1171Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as COSV99539772; called by muse, mutect2
- LRIG3 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1416463564, COSV100292357; called by muse, mutect2
- LRRC4C | c.1608C>G p.I536M | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53432129; called by muse, mutect2, varscan2
- LRRTM1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54444297; called by muse, mutect2, varscan2
- MAP2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52299678; called by muse, mutect2, varscan2
- MEPE | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV63073475; called by muse, mutect2, varscan2
- METTL8 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV64549289; called by muse, mutect2, varscan2
- MFRP | c.418T>G p.F140V (on ENST00000449574; = p.F516V on NM_031433.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100264659; called by muse, mutect2
- MGAT4B | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52978688; called by muse, mutect2
- MMS22L | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51523551; called by muse, mutect2, varscan2
- MOB3C | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV54719876; called by muse, mutect2, varscan2
- MPP2 | c.769C>T p.H257Y (on ENST00000461854 / NM_001278372.2; = p.H233Y on NM_005374.5) | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.464); catalogued as COSV52237779; called by muse, mutect2, varscan2
- MRGPRE | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs368971331; called by muse, mutect2, varscan2
- MROH2B | c.4399G>C p.E1467Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV68186956; called by muse, mutect2, varscan2
- MTCL1 | c.5101G>C p.E1701Q (on ENST00000306329 / NM_001378206.1; = p.E1382Q on NM_015210.4) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100094261, COSV60408911; called by muse, mutect2
- MTHFD1 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV53702070; called by muse, mutect2
- MYO1G | c.2476C>T p.R826C | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201850845, COSV51855596; called by muse, mutect2, varscan2
- MYO9B | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.445); catalogued as COSV68281142; called by muse, mutect2
- NFAT5 | c.715C>G p.Q239E | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1269098061, COSV63030016; called by muse, mutect2
- NFKBIB | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58004246; called by muse, mutect2, varscan2
- NLRX1 | c.2018C>A p.S673* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99423536; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 29/94 reads (31%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NUP107 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV57496293; called by muse, mutect2, varscan2
- NUP214 | c.1943C>A p.S648* | Nonsense Mutation (SNP) | VAF 89/202 reads (44%) | catalogued as COSV100845061; called by muse, mutect2, varscan2
- NYNRIN | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV66843741; called by muse, mutect2, varscan2
- OR1L3 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV59170285; called by muse, mutect2, varscan2
- OR2B2 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100308000; called by muse, mutect2
- OR7A17 | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100541539; called by muse, mutect2, varscan2
- PAGE4 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (1); PolyPhen possibly damaging (0.89); catalogued as COSV54334913; called by muse, mutect2, varscan2
- PDE2A | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100557518; called by muse, varscan2
- PIK3CD | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63127611; called by muse, mutect2
- PKLR | c.1499C>A p.A500D | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV61361872; called by muse, mutect2
- PLEKHG4B | c.1510G>A p.V504M (on ENST00000283426; = p.V860M on NM_052909.5) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs754520403, COSV52042902; called by muse, mutect2, varscan2
- POLR1A | c.4777G>A p.E1593K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV55696077; called by muse, mutect2, varscan2
- PRRT3 | c.1172-1G>A p.X391_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as rs968032460, COSV99926233; called by muse, mutect2
- PRTG | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); catalogued as COSV66839292; called by muse, mutect2, varscan2
- PSAPL1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs760126624, COSV59843827; called by muse, mutect2, varscan2
- PTPN23 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55546279; called by muse, mutect2, varscan2
- RAB3IP | c.331A>G p.T111A (on ENST00000550536 / NM_175623.4; = p.T95A on NM_022456.5) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as COSV56085159; called by muse, mutect2, varscan2
- RAB6C | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV69339667; called by muse, mutect2
- RADX | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as COSV65317787, COSV65319445; called by muse, mutect2, varscan2
- RBM10 | c.128C>A p.S43* | Nonsense Mutation (SNP) | VAF 24/25 reads (96%) | catalogued as COSV100237137, COSV61311837; called by muse, mutect2, varscan2
- RBM25 | c.2061G>C p.K687N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.267); catalogued as COSV56201336; called by muse, mutect2, varscan2
- RNF10 | c.894G>C p.K298N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV58044542, COSV58046836; called by muse, mutect2, varscan2
- RPP38 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); catalogued as COSV65382691; called by muse, mutect2
- RPS4X | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.377); catalogued as COSV100289178, COSV60181901; called by muse, mutect2, varscan2
- RSF1 | c.4030G>C p.E1344Q | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); catalogued as COSV57842928; called by muse, mutect2, varscan2
- RTEL1 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770742969, COSV58897837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTKN2 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV59523352; called by muse, mutect2, varscan2
- SAGE1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV61015459; called by muse, mutect2, varscan2
- SCN4A | c.4591G>A p.E1531K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV71127528; called by muse, mutect2
- SDHB | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV64965488; called by muse, mutect2, varscan2
- SEL1L2 | c.1168-1G>A p.X390_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as rs1265980735, COSV53155005; called by muse, mutect2
- SERPINB4 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as COSV61985601; called by muse, mutect2, varscan2
- SHE | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59072035; called by muse, mutect2, varscan2
- SIGLEC9 | c.527del p.P176Lfs*2 | Frame Shift Del (DEL) | VAF 39/160 reads (24%) | catalogued as COSV51584299; called by mutect2, pindel, varscan2
- SLC12A2 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.186); catalogued as COSV52467915, COSV52473407; called by muse, mutect2, varscan2
- SLC15A1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs199996553; called by muse, mutect2, varscan2
- SLC35G3 | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV52010525, COSV52012034; called by muse, mutect2
- SLC4A3 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as rs753995141, COSV99812258; called by muse, varscan2
- SLC4A8 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV60648940; called by muse, mutect2, varscan2
- SNRPE | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV65843362; called by muse, mutect2, varscan2
- SPAG5 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.358); catalogued as rs539760516, COSV58803049; called by muse, mutect2
- SRGAP1 | c.1947G>T p.M649I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61900746; called by muse, mutect2, varscan2
- SRP72 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100714230; called by muse, mutect2
- SRSF7 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57447801; called by muse, mutect2, varscan2
- SSTR3 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60730752; called by muse, mutect2
- ST6GALNAC5 | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 32/188 reads (17%) | PolyPhen benign (0.394); catalogued as COSV59568873; called by muse, mutect2, varscan2
- SYNE1 | c.13563G>T p.M4521I (on ENST00000367255 / NM_182961.4; = p.M4450I on NM_033071.3) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.23); catalogued as COSV55039242; called by muse, mutect2, varscan2
- SYNE1 | c.12877G>A p.E4293K (on ENST00000367255 / NM_182961.4; = p.E4222K on NM_033071.3) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV55039274; called by muse, mutect2, varscan2
- SYP | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs782397970, COSV54296181; called by muse, mutect2, varscan2
- TAC4 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as COSV58004404; called by muse, mutect2
- TANC2 | c.1477C>G p.L493V | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV67332926, COSV67337881; called by muse, mutect2, varscan2
- TARBP1 | c.3775C>G p.Q1259E | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs935607466, COSV50184847, COSV50203977; called by muse, mutect2
- TBC1D9B | c.3473C>T p.S1158L (on ENST00000356834 / NM_198868.3; = p.S1141L on NM_015043.4) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.95); catalogued as rs190324553; called by muse, mutect2, varscan2
- TET3 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.087); catalogued as COSV59881906, COSV99996132; called by muse, mutect2, varscan2
- TET3 | c.990G>C p.Q330H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV59881913, COSV59882627; called by muse, mutect2, varscan2
- TMEM245 | c.1736C>G p.S579C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV65823650; called by muse, mutect2, varscan2
- TMX4 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs1406791384, COSV55681640; called by muse, mutect2, varscan2
- TNXB | c.6634G>A p.A2212T (on ENST00000647633; = p.A1965T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV64483545; called by muse, mutect2, varscan2
- TOGARAM1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.237); catalogued as COSV61888865; called by muse, mutect2, varscan2
- TRMT6 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.5); catalogued as COSV52544564, COSV99177619; called by muse, mutect2, varscan2
- TTBK2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV99141034; called by muse, mutect2
- TYMS | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV51894131; called by muse, mutect2, varscan2
- UHRF1 | c.1997C>T p.S666F (on ENST00000612630 / NM_001290050.1; = p.S679F on NM_013282.4) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs1049055692, COSV99503243; called by muse, mutect2
- UPF1 | c.1201G>C p.E401Q (on ENST00000599848 / NM_001297549.2; = p.E390Q on NM_002911.4) | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV53199015, COSV53200443, COSV99439268; called by muse, mutect2
- UPRT | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV64912551; called by muse, mutect2, varscan2
- UQCC2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 151/326 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV65268674; called by muse, mutect2, varscan2
- USP17L2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.394); catalogued as rs375221330; called by muse, mutect2, varscan2
- VPS52 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs752665333, COSV71403559; called by muse, mutect2, varscan2
- WDR45B | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101124378; called by muse, mutect2
- XKR9 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV101281799; called by muse, mutect2
- YBX1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV58439277; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2127G>T p.K709N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs1477015772, COSV58743604; called by muse, varscan2
- ZKSCAN5 | c.2191G>C p.D731H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV58743613; called by muse, varscan2
- ZKSCAN5 | c.2424G>A p.M808I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV58743621; called by muse, mutect2, varscan2
- ZMYND8 | c.589A>G p.T197A (on ENST00000311275 / NM_001363741.2; = p.T217A on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53692510; called by muse, mutect2, varscan2
- ZMYND8 | c.193C>T p.P65S (on ENST00000311275 / NM_001363741.2; = p.P85S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53692539; called by muse, mutect2, varscan2
- ZNF229 | c.2415C>A p.F805L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV52163632; called by muse, mutect2, varscan2
- ZNF251 | c.1663C>G p.L555V | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs200819625, COSV52958524; called by muse, mutect2, varscan2
- ZNF251 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV99478048; called by muse, mutect2, varscan2
- ETV6 | c.1293dup p.D432Rfs*13 | Frame Shift Ins (INS) | VAF 44/170 reads (26%) | called by mutect2, pindel, varscan2
- FRG2C | c.608T>A p.L203Q | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- GALK2 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2
- IGKV5-2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KDM6A | c.1648dup p.V550Gfs*3 | Frame Shift Ins (INS) | VAF 45/67 reads (67%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- NCOA4 | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SSX5 | c.425C>G p.S142* (on ENST00000347757 / NM_175723.1; = p.S183* on NM_021015.4) | Nonsense Mutation (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
- TASOR | c.3201C>G p.F1067L (on ENST00000355628 / NM_001365636.2; = p.F691L on NM_015224.3) | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- TRGC2 | c.56T>A p.I19N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, varscan2
- ZNF281 | c.2422C>G p.Q808E | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2
- A4GNT | c.945C>T p.H315= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV52629573, COSV52630136; called by muse, mutect2
- ADGRE5 | c.2322C>G p.L774= (on ENST00000242786 / NM_078481.4; = p.L681= on NM_001784.5) | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs781089508, COSV54392541; called by muse, mutect2, varscan2
- AGAP1 | c.528G>A p.V176= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as COSV58333265; called by muse, mutect2, varscan2
- AGER | c.108G>A p.L36= | Silent (SNP) | VAF 11/150 reads (7%) | catalogued as rs1446355296, COSV66719336; called by muse, mutect2
- AIF1L | c.270G>A p.K90= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV55990694; called by muse, mutect2, varscan2
- ALYREF | c.528C>T p.V176= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs1459812527, COSV100485739; called by muse, mutect2
- AMIGO3 | c.507C>T p.L169= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as COSV57539388; called by muse, mutect2, varscan2
- APOBEC2 | c.120G>A p.E40= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV55143142; called by muse, mutect2, varscan2
- ARHGAP33 | c.822G>A p.L274= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV50135857; called by muse, mutect2, varscan2
- ASB15 | c.1296G>C p.L432= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV51927731; called by muse, mutect2, varscan2
- ATP8A2 | c.2838C>G p.L946= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV54964711; called by muse, mutect2, varscan2
- ATP8B3 | c.36C>A p.T12= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV50083264; called by muse, mutect2, varscan2
- BMPER | c.1719G>C p.S573= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV51825790, COSV99779691; called by muse, mutect2, varscan2
- CACNA1A | c.1800C>G p.L600= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as CD163650, COSV64204920; called by muse, mutect2, varscan2
- CAMTA1 | c.2463C>T p.L821= | Silent (SNP) | VAF 51/180 reads (28%) | catalogued as rs1229847241, COSV57914554; called by muse, mutect2, varscan2
- CARF | c.366G>A p.Q122= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as rs1375990325, COSV57548783; called by muse, mutect2, varscan2
- CDH16 | c.1524G>A p.G508= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs756978582, COSV55338289; called by muse, mutect2, varscan2
- CENPJ | c.2617T>C p.L873= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV67883829; called by muse, mutect2, varscan2
- CEP170B | c.2595C>T p.L865= (on ENST00000453495; = p.L794= on NM_015005.3) | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV69025579; called by muse, mutect2, varscan2
- CFH | c.3372G>A p.P1124= | Silent (SNP) | VAF 31/45 reads (69%) | catalogued as rs41265217, COSV66407479; called by muse, mutect2, varscan2
- CLIC1 | c.597C>T p.I199= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- CUBN | c.9609A>T p.T3203= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV64721702; called by muse, mutect2, varscan2
- CYFIP1 | c.2802G>A p.L934= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- CYP2B6 | c.870C>T p.L290= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100137572, COSV57844902; called by mutect2, varscan2
- DNAH17 | c.9984C>A p.V3328= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV67758477; called by muse, mutect2, varscan2
- DUS2 | c.1305C>T p.G435= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV62709232; called by muse, mutect2, varscan2
- ELAPOR1 | c.1128G>A p.K376= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV64040841; called by muse, mutect2, varscan2
- ETV6 | c.363G>T p.L121= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV67152197, COSV67153915; called by muse, mutect2, varscan2
- FN1 | c.945C>G p.V315= | Silent (SNP) | VAF 82/139 reads (59%) | catalogued as COSV60558533; called by muse, mutect2, varscan2
- GALNT12 | c.1551C>T p.I517= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs878855094, COSV66663228; ClinVar: likely benign; called by muse, mutect2, varscan2
- GEMIN5 | c.957G>A p.R319= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV53562653; called by mutect2, varscan2
- GK2 | c.45G>T p.A15= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV62627760, COSV62628032; called by muse, mutect2, varscan2
- GLB1 | c.378C>T p.I126= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV56566147; called by muse, mutect2
- GPC5 | c.1467C>A p.G489= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV65613410; called by muse, mutect2, varscan2
- GRIA1 | c.924G>A p.R308= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV53604180; called by muse, mutect2, varscan2
- H2BC15 | c.72G>A p.K24= | Silent (SNP) | VAF 130/298 reads (44%) | catalogued as rs776712511, COSV100356855, COSV57586152; called by muse, varscan2
- HDAC3 | c.243C>T p.F81= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV51838072; called by muse, mutect2, varscan2
- HNF1A | c.15G>C p.L5= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV57464676; called by muse, mutect2, varscan2
- IFNA21 | c.312C>G p.L104= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV66518593; called by muse, mutect2, varscan2
- IGFBP4 | c.390C>G p.P130= | Silent (SNP) | VAF 13/238 reads (5%) | catalogued as COSV54097994; called by muse, mutect2
- IMPDH1 | c.795G>A p.A265= (on ENST00000470772 / NM_001142573.2; = p.A351= on NM_000883.4) | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs954543590, COSV58317181; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRX2 | c.387C>T p.L129= | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as COSV57412440; called by muse, mutect2, varscan2
- JUP | c.1914C>T p.N638= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs368772249, COSV100159840; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNAB1 | c.1206G>A p.E402= (on ENST00000490337 / NM_172160.3; = p.E391= on NM_003471.3) | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV54019976, COSV54021793; called by muse, mutect2, varscan2
- KIF21B | c.1365C>T p.L455= | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as rs775355566, COSV59761986; called by muse, mutect2, varscan2
- KPNA2 | c.279G>A p.Q93= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV57858334; called by muse, mutect2, varscan2
- LAMA1 | c.1488C>T p.N496= | Silent (SNP) | VAF 78/290 reads (27%) | catalogued as rs781121049, COSV67533529, COSV67540434; called by muse, mutect2, varscan2
- LRIT1 | c.744G>A p.L248= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs1036150747, COSV64513170; called by muse, mutect2, varscan2
- MAP3K10 | c.960G>A p.L320= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV53423826; called by muse, mutect2, varscan2
- MED1 | c.1260C>T p.L420= | Silent (SNP) | VAF 9/162 reads (6%) | catalogued as COSV56127114; called by muse, mutect2
- MFSD14B | c.1098C>G p.V366= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV64701377; called by muse, mutect2, varscan2
- MLXIP | c.1380G>A p.L460= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs772147433, COSV59836786; called by muse, mutect2, varscan2
- MRPL41 | c.231C>G p.L77= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99479882; called by muse, mutect2
- MTMR7 | c.1092G>A p.K364= | Silent (SNP) | VAF 8/163 reads (5%) | catalogued as COSV51668458; called by muse, mutect2
- MTX3 | c.891G>A p.L297= (on ENST00000512528 / NM_001363818.2; = p.L236= on NM_001167741.2) | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV72590979; called by muse, mutect2, varscan2
- MUC5B | c.13932G>A p.G4644= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV71594206; called by muse, mutect2, varscan2
- MYO18A | c.4632C>A p.L1544= | Silent (SNP) | VAF 9/169 reads (5%) | catalogued as COSV62870274; called by muse, mutect2
- MYO6 | c.1011C>T p.L337= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV64120162; called by muse, mutect2, varscan2
- NCEH1 | c.990C>T p.S330= (on ENST00000538775; = p.S290= on NM_020792.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/77 reads (66%) | catalogued as rs1162074019, COSV56436242; called by muse, mutect2, varscan2
- NFYC | c.345C>T p.I115= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs139444755; called by muse, mutect2, varscan2
- NINL | c.1470G>A p.L490= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV54005840; called by muse, mutect2
- NOS2 | c.831C>T p.I277= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as rs1327951373, COSV58225969; called by muse, mutect2
- NPTXR | c.687C>A p.T229= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV60728941, COSV60729561; called by muse, mutect2, varscan2
- OGDHL | c.633C>T p.F211= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV65103622; called by muse, mutect2, varscan2
- OR10A2 | c.411C>T p.F137= | Silent (SNP) | VAF 72/185 reads (39%) | catalogued as COSV56299971; called by muse, mutect2, varscan2
- OR5B21 | c.651C>T p.F217= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs267603028, COSV64482092; called by muse, mutect2, varscan2
- PCDH12 | c.3150G>A p.L1050= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV51522061; called by muse, mutect2, varscan2
- PDE10A | c.2256G>A p.L752= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV63101816; called by muse, mutect2, varscan2
- POLR2J2 | c.31T>C p.L11= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV100330846; called by muse, mutect2, varscan2
- RAB37 | c.411G>T p.V137= (on ENST00000392613 / NM_001006638.3; = p.V130= on NM_175738.5) | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs765627620, COSV52854104; called by muse, mutect2, varscan2
- RADX | c.1455T>C p.F485= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100998711; called by muse, mutect2, varscan2
- RASGRP1 | c.1578C>T p.F526= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs1488647857, COSV100171649; called by muse, mutect2, varscan2
- REXO5 | c.81G>A p.G27= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV99758868; called by muse, mutect2, varscan2
- RGS13 | c.174C>T p.D58= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as rs768100083, COSV67346384; called by muse, varscan2
- S1PR4 | c.957C>T p.L319= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as rs963082455, COSV55740895; called by muse, mutect2
- SIK3 | c.2559C>G p.V853= (on ENST00000445177 / NM_001366686.2; = p.V811= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV52619098; called by muse, mutect2, varscan2
- SLC45A4 | c.1419G>A p.Q473= (on ENST00000517878 / NM_001286646.2; = p.Q422= on NM_001080431.2) | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV50149524; called by muse, mutect2, varscan2
- SLC4A8 | c.1918C>T p.L640= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV60655849; called by muse, varscan2
- SLC7A13 | c.291C>T p.L97= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV52537089, COSV99878352; called by muse, mutect2
- SOX17 | c.1224C>T p.Y408= | Silent (SNP) | VAF 47/77 reads (61%) | catalogued as COSV52027046; called by muse, mutect2, varscan2
- SPIRE1 | c.792G>A p.L264= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV59159437; called by muse, mutect2, varscan2
- ST8SIA6 | c.1164C>G p.L388= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as rs1564396837, COSV66470108; called by muse, mutect2, varscan2
- STAC | c.877T>C p.L293= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV99829257; called by muse, mutect2, varscan2
- STKLD1 | c.1057C>T p.L353= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV64313852; called by muse, mutect2, varscan2
- STXBP5 | c.2778C>T p.I926= (on ENST00000321680 / NM_001127715.2; = p.I890= on NM_139244.4) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV51655271; called by muse, mutect2, varscan2
- SVOP | c.1524G>A p.L508= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as COSV54469802; called by muse, mutect2, varscan2
- SYVN1 | c.171G>A p.L57= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV53696436, COSV99589311; called by muse, mutect2, varscan2
- TAF1B | c.1245A>G p.K415= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99721733; called by muse, mutect2, varscan2
- TAF4B | c.375G>A p.P125= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs765439658, COSV52303712; called by muse, mutect2, varscan2
- TIAM1 | c.555C>G p.L185= | Silent (SNP) | VAF 14/171 reads (8%) | catalogued as COSV54562923; called by muse, mutect2
- TMC8 | c.1314C>G p.T438= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as COSV59210585; called by muse, mutect2, varscan2
- TMEM25 | c.315C>A p.L105= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV57097318; called by muse, mutect2, varscan2
- TRIM10 | c.381C>T p.H127= | Silent (SNP) | VAF 97/159 reads (61%) | catalogued as rs745992253, COSV64989996; called by muse, mutect2, varscan2
- TSC22D2 | c.705G>T p.A235= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs762378370, COSV62622286, COSV62623052; called by muse, mutect2, varscan2
- TUBA3D | c.1352G>A p.*451= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as COSV100342187; called by muse, varscan2
- URGCP | c.744G>A p.G248= (on ENST00000453200 / NM_001077663.3; = p.G239= on NM_017920.4) | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV56250209; called by muse, mutect2, varscan2
- USP11 | c.981C>A p.L327= (on ENST00000218348; = p.L284= on NM_001371072.1) | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99510576; called by muse, mutect2
- ZNF875 | c.867C>T p.I289= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV60992645, COSV60992708; called by muse, mutect2, varscan2
- GALNT10 | c.568+17492G>A | Intron (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99768019; called by muse, mutect2, varscan2
- H2BP2 | chr1:143874804 G>C | 3'Flank (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- H4C11 | c.-1C>T | 5'UTR (SNP) | VAF 61/126 reads (48%) | catalogued as rs766209909, COSV100747928; called by muse, mutect2, varscan2
- OR56A3 | chr11:5948295 C>G | 3'Flank (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100289971; called by muse, mutect2
- XIST | n.7371C>T | RNA (SNP) | VAF 28/44 reads (64%) | called by muse, mutect2, varscan2
